Gene-level copy-number profile of tumor specimen BLGSP-71-06-00008-01B from CGCI case BLGSP-71-06-00008, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 5.4 years (1,975 days).
Specimen BLGSP-71-06-00008-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a7eedcfb-e3a7-4557-932f-7d055766abfc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00008-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/00f5b75a-58ca-437c-9bdc-ec68d056f5e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 951; copy number 2: 56,192; copy number 3: 932; copy number 4: 174; copy number 5: 3; copy number 6: 2; copy number 8: 2; copy number 12: 1; copy number 13: 1; copy number 28: 1.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes (within-gene range 0–2): PRAMEF6, PRAMEF28P.
- chr1:13,060,869–13,062,229, 1 gene (within-gene range 0–1): HNRNPCL3.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–3) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–3): IGHVIII-47-1, IGHV3-48.
- chr21:43,107,942–43,168,646, 1 gene (within-gene range 0–28): AP001631.2.
- chr21:43,159,066–43,162,277, 1 gene: AP001631.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:63,449,819–63,456,687, 1 gene, copy number 6: ZNF734P.
- chr7:63,632,608–63,636,617, 1 gene, copy number 13: AC006015.1.
- chr9:65,189,995–65,193,610, 1 gene, copy number 8: BMS1P12.
- chr17:46,292,733–46,337,794, 2 genes, copy number 5 (within-gene range 4–5): LRRC37A, RN7SL656P.
- chr21:43,092,956–43,107,570, 1 gene, copy number 12: U2AF1.
- chr21:43,115,334–43,141,092, 2 genes, copy number 5–28: MRPL51P2, FRGCA.
- chr21:43,169,008–43,172,805, 1 gene, copy number 8: CRYAA.
- chr21:43,461,960–43,479,534, 1 gene, copy number 6 (within-gene range 1–6): LINC00313.

Autosomal genes at a single copy (total copy number 1): 811. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
